Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PN, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PN-01A (Primary Tumor).

[page 1 of 2]
by 8/31/11		

Neck
and Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:
Papillary carcinoma.

Specimens Submitted:

- 1: Left thyroid lobe and isthmus
- 2: Right thyroid lobe

DIAGNOSIS:

1. Left thyroid lobe and isthmus:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type
and ossification

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.3 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

105-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS 073.9

by
8/31/11

[page 2 of 2]
Not Identified
Non-Neoplastic Thyroid:
Mild nodular hyperplasia
Parathyroid Glands:
Not identified

2. **Thyroid, right lobe; hemithyroidectomy:**
- Nodular thyroid hyperplasia
- No parathyroid identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and is labeled "left thyroid lobe and isthmus". It consists of a thyroid lobe measuring 3x2x2 cm and weighing 5 g. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a firm, calcified nodule measuring 1.3x1.2x1.0 cm. Entirely submitted.

Summary of sections:

N - Nodule
RS - remaining sections (entire lobe)
IS-isthmus (entire)

2). The specimen is received fresh and is labeled "right thyroid lobe ". It consists of a thyroid lobe measuring 4x2x1.2 cm and weighing 4.5 g. The lobe is inked black posterior and blue anterior. Serial sectioning reveals unremarkable thyroid parenchyma. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: Left thyroid lobe and isthmus

Block	Sect. Site	PCs
1	is	1
3	n	3
2	rs	2

Part 2: Right thyroid lobe

Block	Sect. Site	PCs
2	u	2

Source: NCI Genomic Data Commons file 18de022c-8ec8-41fb-85e6-06e54011bbff (TCGA-DJ-A2PN.894CA3E0-0279-45E2-8762-E53EEBE01272.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).